Surgical pathology report (de-identified scan), TCGA case TCGA-OD-A75X, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Saint Mary's Health Care, specimen TCGA-OD-A75X-06A (Metastatic).

[page 1 of 3]
Surg Path Final Report

* Final Report *

ICD O-3

* Final Report *

Melanoma, malignant NOS
8720/3
Site Odung, upper lobe
C34.1
JW 8/21/13

SURG PATH FINAL REPORT

SURGICAL PATHOLOGY

Collected:

Accession:

Physician:

PROCEDURE

Flexible bronchoscopy, left robotic assisted thoracic surgery, left upper lobe posterior segmentectomy

HISTORY

Left upper lobe metastatic melanoma

GROSS

Part A. Received fresh, labeled "posterior segment left upper lobe," is a 12 x 4.5 x 2.5 cm, 41-gram wedge-shaped portion of lung. The pleural surface shows a puckering over a 2 cm zone. Deep to this puckering is a 3 x 2.5 x 2.5 cm tan mass. This mass is 0.5 cm from the staple line surgical margin. The remainder of the pleural surface is pink-red and the uninvolved cut surface is pink-red. A portion of the surgical margin is submitted for frozen section. A sample of the tissue is submitted for research studies per protocol.

Representative sections submitted in six cassettes. Sent for TCGA research.

Sections are taken as follows:

- 1 as frozen
- 2-3 as green inked puckered mass
- 4-5 as additional mass
- 6 as uninvolved lung

Part B. Received fresh, labeled "wedge resection left lower lobe," is a 5.5 x 1 x 0.6 cm, 1 gram wedge-shaped portion of lung. The pleural surface is pink-red and shows a black 0.5 cm nodule. A portion of the nodule is submitted for frozen section. Submitted entirely in two cassettes.

Printed by:
Printed on:

Page 1 of 3
(Continued)

[page 2 of 3]
Surg Path Final Report

* Final Report *

Sections are taken as follows:

- 1 as frozen
- 2 as remainder of specimen

Part C. Received fresh, labeled "wedge resection left upper," is a wedge-shaped 2.5 x 0.4 x 0.3 cm fragment that weighs less than 1 gram. It has a pink-red pleural surface with a 0.2 cm black nodule. All of the specimen except the staple line is submitted for frozen section in one cassette.

Part D. Received in formalin, labeled "wedge of left lower lobe," is a 1.5 x 0.6 x 0.5 x 0.5 cm less than 1 gram wedge-shaped portion of lung. The pleural surface is red-black. The tissue on cut section is red. All of the tissue except the staple line is submitted in one cassette.

Total time in 10% neutral buffered formalin from collection through processing: Total cold ischemia time:

FROZEN SECTION DIAGNOSIS

- A. Margins negative.
- B, C. Left lower lobe and left upper lobe benign intraparenchymal lymph nodes.

DIAGNOSIS

- A: LUNG, LEFT UPPER LOBE, POSTERIOR SEGMENT, SEGMENTECTOMY:
- METASTATIC MELANOMA (3 CM).
- MARGINS OF RESECTION ARE FREE OF MALIGNANCY.

- B: LYMPH NODE, LEFT LOWER LOBE, EXCISION:
- ONE BENIGN INTRAPARENCHYMAL LYMPH NODE.

- C: LUNG, LEFT UPPER LOBE, WEDGE RESECTION:
- BENIGN LUNG PARENCHYMA. NO MALIGNANCY IS IDENTIFIED.

- D: LUNG, LEFT LOWER LOBE, WEDGE RESECTION:
- ONE BENIGN INTRAPARENCHYMAL LYMPH NODE.

88331 (A), 88331 (B), 88331 (C)
88307 (A), 88305 (B), 88307 (C), 88307 (D)

Printed by:
Printed on:

Page 2 of 3
(Continued)

[page 3 of 3]
Surg Path Final Report

* Final Report *

197.0 FOR EACH PART

(Electronic Signature)

Completed Action List:

* Order by on

Type: Surg Path Final Report
Date:
Status: Auth (Verified)
Title: SURG PATH FINAL REPORT
Encounter info:
Contributor system:

Printed by:
Printed on:

Page 3 of 3
(End of Report)

Source: NCI Genomic Data Commons file f048d703-c534-45b2-a693-e5826031f546 (TCGA-OD-A75X.ADB81B04-707A-48A3-ACCF-685BC6908F93.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).